CCG case CUPP-B4OA — CCG-CUPP: Center for Cancer Genomics (CCG) Cancers of Unknown Primary Project (CUPP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/08db02b3-01b3-4dfa-88eb-48ca05a3ab14

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: Spain; Year of birth: 1978; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C80; Tissue or organ of origin: Unknown primary site; Site of resection or biopsy: Intrathoracic lymph nodes; Classification of tumor: metastasis; Age at diagnosis: 41.2 years (15,063 days); Year of diagnosis: 2019; Method of diagnosis: Biopsy; AJCC staging edition: 8th; AJCC clinical N: N2a; AJCC clinical M: M1; AJCC clinical stage: Stage IV; AJCC pathologic N: N2; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Sites of involvement: Brain, NOS / Lymph node, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 6; Lymph nodes tested: 7; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Treatment Ongoing; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Treatment Ongoing; Timepoint category: Postoperative.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Residual disease: RX; Timepoint category: First Treatment.
2. Progression of the lymph nodes of head, face and neck (histology not recorded by GDC). Age at diagnosis: 41.6 years (15,203 days); Year of diagnosis: 2019; Days to diagnosis: 140 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease; Treatment outcome: Treatment Ongoing.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80; ECOG performance status: 2.
- Day 140 (progression): Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph nodes of head, face and neck; Days to progression: 140 days.
- Days to follow up: 154 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 68 kg; Height: 177 cm; BMI: 21.7.

Exposures
- Tobacco smoking status: Smoker at Diagnosis; Pack years smoked: 27; Tobacco smoking onset year: 1992.

Family history
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Thyroid Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Testicular Cancer; Relationship sex at birth: male.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample CUPP-B4OA-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B4OA-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample CUPP-B4OA-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide CUPP-B4OA-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
